Somatic mutation profile of tumor specimen MMRF_1345_3_BM_CD138pos (aliquot MMRF_1345_3_BM_CD138pos_T1_KHS5U_L13421) from MMRF case MMRF_1345, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.8 years (22,223 days).
Specimen MMRF_1345_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a702dac5-7fd8-479a-bacd-7fd09a9ac37b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1345_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1345_1_PB_Whole_C1_KHS5U_L13758; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8075c5f3-cebf-4752-bf14-c137ef476eb8

The open-access MAF lists 180 somatic variants for this specimen: 74 protein-altering or splice-affecting, 23 silent, 83 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, 3'UTR 44, Silent 23, Intron 18, 5'UTR 9, 5'Flank 6, Nonsense Mutation 5, 3'Flank 3, RNA 3, Splice Site 3, Splice Region 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 22/63 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RB1 | c.137+1G>T p.X46_splice | Splice Site (SNP) | VAF 10/16 reads (63%) | hotspot (GDC flag); catalogued as rs1131690855, CS051699, CS062095, COSV57334881; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS2 | c.2915G>A p.R972H | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs370478581, COSV99281776; called by muse, mutect2, varscan2
- ADCY2 | c.2229C>G p.S743R | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV57861132; called by muse, mutect2, varscan2
- BRWD3 | c.486C>A p.F162L | Missense Mutation (SNP) | VAF 68/215 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as COSV64745265; called by muse, mutect2, varscan2
- C4orf54 | c.1152C>A p.F384L | Missense Mutation (SNP) | VAF 126/360 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.691); catalogued as COSV72767064; called by muse, mutect2, varscan2
- COPA | c.1570A>G p.I524V | Missense Mutation (SNP) | VAF 154/294 reads (52%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs1172763825, COSV54107285; called by muse, mutect2, varscan2
- ENKUR | c.230dup p.N77Kfs*3 | Frame Shift Ins (INS) | VAF 47/115 reads (41%) | catalogued as rs749430462; called by mutect2, varscan2
- FANCA | c.3313T>A p.C1105S | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as COSV59796994; called by muse, mutect2, varscan2
- FUT2 | c.264G>A p.M88I | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as rs1434525456; called by muse, mutect2, varscan2
- GUCY2D | c.2107G>A p.A703T | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.643); catalogued as rs1270111845; called by muse, mutect2, varscan2
- GYG1 | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 113/444 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.059); catalogued as rs1226277771; called by muse, mutect2, varscan2
- IGHV2-70 | c.100A>G p.T34A | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs570621406; called by muse, varscan2
- IGHV2-70 | c.83C>A p.P28H | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770314362; called by muse, varscan2
- MGAT4C | c.762C>A p.F254L | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59830235; called by muse, mutect2, varscan2
- MRPS2 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 153/303 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761675294; called by muse, mutect2, varscan2
- NT5DC3 | c.1094A>G p.Y365C | Missense Mutation (SNP) | VAF 81/254 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775220161; called by muse, mutect2, varscan2
- OPN3 | c.946-8C>T | Splice Region (SNP) | VAF 111/451 reads (25%) | catalogued as rs376646156; called by muse, mutect2, varscan2
- PCDHGA2 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 195/402 reads (49%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.035); catalogued as COSV53994700; called by muse, mutect2, varscan2
- RXRG | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs899161200, COSV63233145; called by muse, mutect2, varscan2
- SBSPON | c.721C>A p.Q241K | Missense Mutation (SNP) | VAF 234/819 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.137); catalogued as COSV52076858; called by muse, mutect2, varscan2
- SLAMF8 | c.742G>T p.V248F | Missense Mutation (SNP) | VAF 108/211 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.276); catalogued as rs767161944; called by muse, mutect2, varscan2
- SPEM2 | c.1297G>A p.V433I | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.178); catalogued as COSV61604365; called by muse, mutect2, varscan2
- STARD3NL | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs750591308; called by muse, mutect2, varscan2
- TDO2 | c.686del p.N229Ifs*11 | Frame Shift Del (DEL) | VAF 40/111 reads (36%) | catalogued as rs1291985502; called by mutect2, pindel, varscan2
- TENT4B | c.1987C>T p.R663C (on ENST00000561678 / NM_001365323.2; = p.R648C on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.201); catalogued as rs574661923, COSV62546332; called by muse, mutect2, varscan2
- TM4SF4 | c.293T>C p.V98A | Missense Mutation (SNP) | VAF 94/195 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as rs575693478; called by muse, mutect2, varscan2
- TMEM185A | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 90/510 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs1173476405; called by muse, mutect2, varscan2
- VSIG8 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs150813505; called by muse, mutect2, varscan2
- XIRP1 | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 250/459 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs35083720; called by muse, mutect2, varscan2
- ZC3H12D | c.841C>T p.H281Y | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as rs891152177; called by muse, mutect2, varscan2
- ZNF90 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 100/305 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as rs1420340893; called by muse, mutect2, varscan2
- ADCY2 | c.2230T>G p.C744G | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ADGRL1 | c.3083A>C p.K1028T (on ENST00000340736 / NM_001008701.3; = p.K1023T on NM_014921.5) | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AHNAK | c.10983G>A p.M3661I | Missense Mutation (SNP) | VAF 90/482 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- ANPEP | c.2431T>G p.F811V | Missense Mutation (SNP) | VAF 107/517 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGAP23 | c.989C>A p.P330H | Missense Mutation (SNP) | VAF 62/88 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCDC3 | c.296T>A p.L99H | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL9A2 | c.1891C>T p.Q631* | Nonsense Mutation (SNP) | VAF 64/188 reads (34%) | called by muse, mutect2, varscan2
- CSE1L | c.2897C>T p.A966V | Missense Mutation (SNP) | VAF 94/373 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- DELEC1 | n.727G>T | Splice Region (SNP) | VAF 122/285 reads (43%) | called by muse, mutect2, varscan2
- DNAH9 | c.3001G>T p.G1001C | Missense Mutation (SNP) | VAF 83/241 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- EXT1 | c.526T>C p.S176P | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- FBN1 | c.5917G>A p.D1973N | Missense Mutation (SNP) | VAF 67/199 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FSIP2 | c.17504T>G p.L5835R | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HDLBP | c.392dup p.L133Afs*14 | Frame Shift Ins (INS) | VAF 18/59 reads (31%) | called by mutect2, pindel, varscan2
- HNRNPH1 | c.254-1G>T p.X85_splice | Splice Site (SNP) | VAF 36/182 reads (20%) | called by muse, mutect2, varscan2
- IGHV1-45 | c.15G>A p.W5* | Nonsense Mutation (SNP) | VAF 28/81 reads (35%) | called by muse, varscan2
- ITSN2 | c.3906_3910del p.R1303Lfs*6 | Frame Shift Del (DEL) | VAF 15/86 reads (17%) | called by mutect2, pindel, varscan2
- MPC1 | c.71+1G>C p.X24_splice | Splice Site (SNP) | VAF 83/238 reads (35%) | called by muse, mutect2, varscan2
- MYH4 | c.1501C>T p.Q501* | Nonsense Mutation (SNP) | VAF 52/176 reads (30%) | called by muse, mutect2, varscan2
- NACC2 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NETO1 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 44/119 reads (37%) | called by muse, mutect2, varscan2
- NFKBIZ | c.446T>A p.I149K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.006); called by muse, varscan2
- OR13H1 | c.771G>C p.M257I | Missense Mutation (SNP) | VAF 75/184 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ORM1 | c.317T>C p.I106T | Missense Mutation (SNP) | VAF 94/348 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- OTULINL | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- PBX3 | c.1298C>G p.S433C | Missense Mutation (SNP) | VAF 97/493 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- POLH | c.1102G>C p.V368L | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- PTGIR | c.870G>T p.W290C | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RFX1 | c.2911C>G p.L971V | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); called by mutect2, varscan2
- RNF128 | c.65T>G p.I22S | Missense Mutation (SNP) | VAF 87/244 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROBO2 | c.3847C>T p.Q1283* | Nonsense Mutation (SNP) | VAF 112/404 reads (28%) | called by muse, mutect2, varscan2
- RRS1 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SLIT3 | c.4028G>A p.C1343Y | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SLITRK4 | c.1095T>G p.N365K | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SMC6 | c.2171T>A p.I724N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SMTNL2 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SOX11 | c.1208G>T p.S403I | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TOX2 | c.76C>A p.L26I | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS41 | c.1033C>T p.L345F | Missense Mutation (SNP) | VAF 67/248 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ZNF281 | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- ZNF330 | c.611A>C p.K204T | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF804B | c.507A>C p.K169N | Missense Mutation (SNP) | VAF 139/481 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- BPIFB3 | c.828C>T p.H276= | Silent (SNP) | VAF 104/338 reads (31%) | called by muse, mutect2, varscan2
- BSN | c.1890T>A p.P630= | Silent (SNP) | VAF 81/353 reads (23%) | called by muse, mutect2, varscan2
- BTNL2 | c.762C>T p.P254= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as rs1320706408; called by muse, mutect2, varscan2
- CEP152 | c.1308C>T p.H436= | Silent (SNP) | VAF 48/267 reads (18%) | catalogued as rs769755378; called by muse, mutect2, varscan2
- COL16A1 | c.3450C>T p.G1150= | Silent (SNP) | VAF 98/269 reads (36%) | catalogued as rs778638036, COSV54702935; called by muse, mutect2, varscan2
- ERAP2 | c.177G>A p.G59= | Silent (SNP) | VAF 58/243 reads (24%) | called by muse, mutect2, varscan2
- GRID2IP | c.321C>T p.C107= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs1175434916; called by muse, mutect2
- IGHV1-46 | c.90G>A p.V30= | Silent (SNP) | VAF 65/192 reads (34%) | catalogued as rs782730082; called by muse, mutect2, varscan2
- IGSF3 | c.1596C>T p.A532= (on ENST00000369486 / NM_001007237.3; = p.A552= on NM_001542.4) | Silent (SNP) | VAF 65/137 reads (47%) | called by muse, mutect2, varscan2
- KLF13 | c.414G>A p.G138= | Silent (SNP) | VAF 20/78 reads (26%) | called by muse, mutect2, varscan2
- LCOR | c.3090G>T p.V1030= | Silent (SNP) | VAF 51/169 reads (30%) | called by muse, mutect2, varscan2
- MAB21L2 | c.273C>T p.D91= | Silent (SNP) | VAF 82/218 reads (38%) | called by muse, varscan2
- MAMDC4 | c.2265G>T p.R755= (on ENST00000445819; = p.R676= on NM_206920.3) | Silent (SNP) | VAF 35/213 reads (16%) | called by muse, mutect2, varscan2
- MISP3 | c.594G>A p.L198= (on ENST00000269720; = p.L56= on NM_001291291.2) | Silent (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- MTCL1 | c.837T>C p.C279= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs1451504257; called by muse, mutect2, varscan2
- RACK1 | c.399T>C p.N133= | Silent (SNP) | VAF 109/273 reads (40%) | called by muse, mutect2, varscan2
- RNF111 | c.1074G>A p.R358= | Silent (SNP) | VAF 18/111 reads (16%) | called by muse, mutect2, varscan2
- ROR2 | c.2739G>A p.E913= | Silent (SNP) | VAF 58/290 reads (20%) | called by muse, mutect2, varscan2
- SLC4A4 | c.1842C>T p.N614= (on ENST00000264485 / NM_001098484.3; = p.N570= on NM_003759.4) | Silent (SNP) | VAF 65/183 reads (36%) | called by muse, mutect2, varscan2
- TCF23 | c.324C>T p.P108= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as rs200237600, COSV56078125; called by muse, mutect2, varscan2
- UMODL1 | c.966C>T p.N322= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as rs376021274; called by muse, mutect2, varscan2
- VPS18 | c.588A>C p.L196= | Silent (SNP) | VAF 102/576 reads (18%) | called by muse, mutect2, varscan2
- WHAMM | c.1959G>A p.P653= | Silent (SNP) | VAF 31/205 reads (15%) | catalogued as rs376165711; called by muse, mutect2, varscan2
- ABHD18 | c.*3206G>T | 3'UTR (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- AC078880.2 | n.682C>T | RNA (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- ACTN1 | c.-203C>T | 5'UTR (SNP) | VAF 27/77 reads (35%) | catalogued as rs1055476332; called by muse, mutect2, varscan2
- AGPAT2 | c.*365C>T | 3'UTR (SNP) | VAF 31/169 reads (18%) | catalogued as rs113127797; called by muse, mutect2, varscan2
- AHCTF1P1 | n.31C>T | RNA (SNP) | VAF 31/76 reads (41%) | called by muse, mutect2, varscan2
- AMOTL1 | c.*4851G>C | 3'UTR (SNP) | VAF 31/66 reads (47%) | called by muse, mutect2, varscan2
- AP000842.1 | n.601T>A | RNA (SNP) | VAF 39/155 reads (25%) | called by muse, mutect2, varscan2
- AP3S2 | c.*261C>A | 3'UTR (SNP) | VAF 58/243 reads (24%) | called by muse, mutect2, varscan2
- API5 | c.*1442T>G | 3'UTR (SNP) | VAF 91/449 reads (20%) | called by muse, mutect2, varscan2
- ARMCX3 | c.*1573G>T | 3'UTR (SNP) | VAF 38/85 reads (45%) | called by muse, mutect2, varscan2
- ATP6V0E2 | c.*112C>G | 3'UTR (SNP) | VAF 96/288 reads (33%) | catalogued as COSV70416932; called by muse, mutect2, varscan2
- ATP8B2 | c.*983C>G | 3'UTR (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122020680 T>C | 5'Flank (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- BCL7A | chr12:122020822 T>G | 5'Flank (SNP) | VAF 57/140 reads (41%) | catalogued as COSV55852134; called by muse, varscan2
- BCL7A | chr12:122020953 T>G | 5'Flank (SNP) | VAF 70/180 reads (39%) | called by muse, varscan2
- BCL7A | chr12:122021022 T>C | 5'Flank (SNP) | VAF 62/180 reads (34%) | called by muse, varscan2
- BST1 | c.*111T>G | 3'UTR (SNP) | VAF 42/117 reads (36%) | called by muse, mutect2, varscan2
- CCNYL1 | c.*2373T>C | 3'UTR (SNP) | VAF 76/190 reads (40%) | catalogued as rs1259594808; called by muse, mutect2, varscan2
- CDC42BPA | c.*1555T>C | 3'UTR (SNP) | VAF 28/115 reads (24%) | called by muse, mutect2, varscan2
- CDH5 | c.1217+11G>A | Intron (SNP) | VAF 19/49 reads (39%) | catalogued as rs367807107; called by muse, mutect2, varscan2
- CMC1 | c.*858A>T | 3'UTR (SNP) | VAF 25/100 reads (25%) | called by muse, mutect2, varscan2
- DACH2 | c.1751-1015T>C | Intron (SNP) | VAF 30/74 reads (41%) | called by muse, mutect2, varscan2
- DCDC2 | c.*2917G>A | 3'UTR (SNP) | VAF 29/77 reads (38%) | called by muse, mutect2, varscan2
- DDX1 | c.1686+50A>T | Intron (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- DDX46 | chr5:134830152 A>G | 3'Flank (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- DIAPH1 | c.*51G>A | 3'UTR (SNP) | VAF 42/186 reads (23%) | called by muse, mutect2, varscan2
- DOK1 | c.*200G>T | 3'UTR (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- DPYSL5 | c.*2422G>A | 3'UTR (SNP) | VAF 45/163 reads (28%) | called by muse, mutect2, varscan2
- ELF5 | c.385+749G>A | Intron (SNP) | VAF 24/125 reads (19%) | called by muse, mutect2, varscan2
- ENPP6 | c.*1977T>G | 3'UTR (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- EPHB6 | c.1751-30C>T | Intron (SNP) | VAF 60/210 reads (29%) | catalogued as rs1458447917; called by muse, mutect2, varscan2
- ERBB4 | c.*3482A>T | 3'UTR (SNP) | VAF 19/60 reads (32%) | called by muse, mutect2, varscan2
- ETNPPL | c.411-15dup | Intron (INS) | VAF 16/42 reads (38%) | catalogued as rs767406209; called by mutect2, varscan2
- EYA2 | c.*325T>A | 3'UTR (SNP) | VAF 23/71 reads (32%) | called by muse, mutect2, varscan2
- FAM102A | c.-282G>A | 5'UTR (SNP) | VAF 52/111 reads (47%) | called by muse, mutect2, varscan2
- FAT4 | c.*47C>A | 3'UTR (SNP) | VAF 97/297 reads (33%) | called by muse, mutect2, varscan2
- FDPS | c.-1-161T>C | Intron (SNP) | VAF 7/8 reads (88%) | called by muse, mutect2, varscan2
- FGD1 | c.*635T>G | 3'UTR (SNP) | VAF 33/65 reads (51%) | called by muse, mutect2, varscan2
- FNIP2 | c.*2421dup | 3'UTR (INS) | VAF 16/64 reads (25%) | catalogued as rs1006467507; called by mutect2, pindel, varscan2
- FSD1L | c.1026-9287A>C | Intron (SNP) | VAF 99/239 reads (41%) | called by muse, mutect2, varscan2
- GCN1 | c.*345del | 3'UTR (DEL) | VAF 34/112 reads (30%) | called by mutect2, pindel, varscan2
- GET1 | c.*902G>T | 3'UTR (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- GSTM4 | c.361-28G>C | Intron (SNP) | VAF 12/32 reads (38%) | called by mutect2, varscan2
- IRX4 | c.408-261C>T | Intron (SNP) | VAF 43/100 reads (43%) | called by muse, mutect2, varscan2
- ITGA1 | c.*401C>G | 3'UTR (SNP) | VAF 29/146 reads (20%) | called by muse, mutect2, varscan2
- KAZN | c.*2770G>A | 3'UTR (SNP) | VAF 84/232 reads (36%) | called by muse, mutect2, varscan2
- KCNIP4 | c.61+251105C>A | Intron (SNP) | VAF 100/310 reads (32%) | called by muse, mutect2, varscan2
- LMBR1 | c.*1326A>G | 3'UTR (SNP) | VAF 19/80 reads (24%) | called by muse, mutect2, varscan2
- LRP2BP | c.-406G>A | 5'UTR (SNP) | VAF 70/216 reads (32%) | called by muse, mutect2, varscan2
- LRRC37A4P | n.5181-11C>T | Intron (SNP) | VAF 59/165 reads (36%) | called by muse, mutect2, varscan2
- LTB | c.162+96G>A | Intron (SNP) | VAF 20/58 reads (34%) | catalogued as rs568160727, COSV53000207, COSV53001296; called by muse, mutect2, varscan2
- MGAM | c.4618+263G>A | Intron (SNP) | VAF 26/35 reads (74%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851347 G>A | 5'Flank (SNP) | VAF 62/140 reads (44%) | catalogued as rs1379330588; called by muse, mutect2, varscan2
- MOB3B | c.*3155T>C | 3'UTR (SNP) | VAF 65/150 reads (43%) | catalogued as rs910375302; called by muse, mutect2, varscan2
- MOCS2 | c.-98A>C | 5'UTR (SNP) | VAF 84/369 reads (23%) | catalogued as rs1207074524; called by muse, mutect2, varscan2
- MON1B | c.-11+66G>A | Intron (SNP) | VAF 32/96 reads (33%) | called by mutect2, varscan2
- NR3C1 | c.*531C>T | 3'UTR (SNP) | VAF 13/87 reads (15%) | called by muse, mutect2, varscan2
- NSMCE3 | c.-49C>G | 5'UTR (SNP) | VAF 28/162 reads (17%) | catalogued as rs544984145; called by muse, mutect2, varscan2
- PINX1 | c.129+105A>C | Intron (SNP) | VAF 13/23 reads (57%) | called by muse, mutect2, varscan2
- PTPRT | c.*5270_*5275dup | 3'UTR (INS) | VAF 22/120 reads (18%) | called by mutect2, varscan2
- RAB10 | c.*1829G>C | 3'UTR (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- RAPGEF5 | c.*4066del | 3'UTR (DEL) | VAF 15/72 reads (21%) | catalogued as rs912717698; called by mutect2, pindel, varscan2
- RGS7BP | c.*2050A>T | 3'UTR (SNP) | VAF 21/94 reads (22%) | called by muse, mutect2, varscan2
- RPRD1B | c.-173G>T | 5'UTR (SNP) | VAF 54/206 reads (26%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.*1626dup | 3'UTR (INS) | VAF 6/30 reads (20%) | called by pindel, varscan2
- RWDD1 | c.*4520A>C | 3'UTR (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2
- SCARA3 | chr8:27676724 G>A | 3'Flank (SNP) | VAF 44/72 reads (61%) | called by muse, mutect2, varscan2
- SNX13 | c.-148G>A | 5'UTR (SNP) | VAF 34/112 reads (30%) | catalogued as rs1191798301; called by muse, mutect2
- SOCS6 | c.-77C>G | 5'UTR (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- STS | c.*1344G>C | 3'UTR (SNP) | VAF 43/108 reads (40%) | called by muse, mutect2, varscan2
- TAF8 | c.*5409dup | 3'UTR (INS) | VAF 15/49 reads (31%) | called by mutect2, pindel, varscan2
- TBC1D30 | c.*2635T>C | 3'UTR (SNP) | VAF 238/627 reads (38%) | called by muse, mutect2, varscan2
- TEAD1 | c.*5528A>T | 3'UTR (SNP) | VAF 23/99 reads (23%) | called by muse, mutect2, varscan2
- TGFBRAP1 | chr2:105266721 T>G | 3'Flank (SNP) | VAF 47/145 reads (32%) | called by muse, mutect2, varscan2
- TRIB2 | c.-474A>C | 5'UTR (SNP) | VAF 30/107 reads (28%) | called by muse, mutect2, varscan2
- TRIM15 | chr6:30163356 T>C | 5'Flank (SNP) | VAF 112/300 reads (37%) | called by muse, mutect2, varscan2
- UNC5C | c.*5357_*5368del | 3'UTR (DEL) | VAF 19/92 reads (21%) | called by mutect2, pindel, varscan2
- USP38 | c.1209+861T>A | Intron (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- ZADH2 | c.*3579A>G | 3'UTR (SNP) | VAF 32/92 reads (35%) | catalogued as rs932674731; called by muse, mutect2
- ZMYM3 | c.*183A>T | 3'UTR (SNP) | VAF 33/128 reads (26%) | called by muse, mutect2, varscan2
- ZNF341 | c.*614C>T | 3'UTR (SNP) | VAF 65/101 reads (64%) | called by muse, mutect2, varscan2
- ZNF445 | c.*185G>A | 3'UTR (SNP) | VAF 54/187 reads (29%) | called by muse, mutect2, varscan2
- ZNF525 | c.142+234dup | Intron (INS) | VAF 16/50 reads (32%) | called by mutect2, varscan2
